Surgical pathology report (de-identified scan), TCGA case TCGA-K6-A3WQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K6-A3WQ-01A (Primary Tumor).

[page 1 of 6]
MRN

Name

Encounter Num

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Reported

Ordering Provider

Status

Time Received

Order Number

Results

Final

Source of Specimen

- A. UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES & OVARIES FOR GROSS-
- B. VAGINAL CUFF TISSUE-
- C. SIGMOID SURFACE TISSUE-
- D. CUL-DE-SAC TISSUE-
- E. LEFT ADENEXAL TISSUE-
- F. RIGHT SIDE WALL TISSUE-
- G. RIGHT PELVIC LYMPH NODES-
- H. LEFT PELVIC LYMPH NODE-
- I. RIGHT SIDE WALL TISSUE #2-
- J. OMENTUM-

FINAL DIAGNOSIS:

- A. UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES & OVARIES FOR GROSS-
- ENDOMETRIAL CARCINOMA.

HISTOLOGIC TYPE: SEROUS TYPE, ADMIXED WITH CLEAR CELL AND ENDOMETRIOID COMPONENTS.

100% endometrial carcinoma,
serous type per TSS pathologist.

HISTOLOGIC GRADE: 3/3.

DEPTH OF INVASION: 14 MM. NEARLY 95% OF MYOMETRIUM.

ICD-0-3

adenocarcinoma, serous

MYOMETRIAL THICKNESS: 15 MM. AT TUMOR SITE.

844113

Site: endometrium C64.1

INVASION OF CERVICAL STROMA: PRESENT.

5-11-12 eo

Pre

AW
5/9/12

[page 2 of 6]
INVASION OF VAGINA: NOT SEEN IN PART "B".

INVASIVE IMPLANTS, SEEN IN UTERINE SEROSA, BILATERAL ADNEXAE, CUL-DE-SAC, RIGHT SIDE WALL (PARTS "F" AND "I"), AND PERICOLIC SOFT TISSUE (PART "C").

METASTATIC CARCINOMA ALSO NOTED IN OMENTUM.

TUMOR SIZE: 3.5 CM IN GREATEST DIMENSION.

TNM STAGE (AJCC, Edition): pT3b, pN1, pM1.

LYMPHATIC (SMALL VESSEL) INVASION: PRESENT.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 1
NUMBER EXAMINED: 2

SPECIMEN TYPE: HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY.

SIZE OF UTERUS: 6 x 4.5 x 3 CM.

ADENOMYOSIS.

NO TUMOR SEEN AT RESECTION MARGINS OF THE SPECIMEN.

B. VAGINAL CUFF TISSUE-

FIBROUS TISSUE, INFLAMED WITH CAUTERY ARTIFACT.

C. SIGMOID SURFACE TISSUE-

INVASIVE CARCINOMA AS SEEN IN PART "A".

D. CUL-DE-SAC TISSUE-

INVASIVE CARCINOMA AS SEEN IN PART "A".

E. LEFT ADNEXAL TISSUE-

INVASIVE CARCINOMA AS SEEN IN PART "A".

F. RIGHT SIDE WALL TISSUE-

INVASIVE CARCINOMA AS SEEN IN PART "A".

G. RIGHT PELVIC LYMPH NODES-

LYMPH NODE, NEGATIVE FOR TUMOR.

H. LEFT PELVIC LYMPH NODE-

LYMPH NODE WITH MICROMETASTASIS. NO EXTRANODAL INVASION SEEN.

SEE NOTE.

NOTE: THE MICROMETASTASIS CONSISTS OF RARE MINUTE CLUSTERS OF TUMOR CELLS. ON IMMUNOSTAINING, THE TUMOR CELLS ARE POSITIVE FOR KERATINS).

Appropriate positive controls were stained along side sections from this case. The control tissue was examined and judged to be technically acceptable.

Prep.

[page 3 of 6]
1. RIGHT SIDE WALL TISSUE #2-
INVASIVE CARCINOMA AS SEEN IN PART "A".
2. OMENTUM
INVASIVE CARCINOMA AS SEEN IN PART "A".
(kgc)

3)

Signed Others

Frozen Section

A. UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES, GROSS EXAM:

-5.2 CM FRIABLE PAPILLATION OCCUPYING THE ENTIRE ENDOMETRIAL CAVITY AND INVADING INTO THE MYOMETRIUM (>50%);

-SHORTENED CERVIX (S/P LEEP), NO TUMOR SEEN GROSSLY IN THE CERVIX.

SECTIONS OF TUMOR AND CERVIX TAKEN FOR RESEARCH STUDY

Frozen section performed by Dr.

Case Clinical Information

PAPILLARY SEROUS UTERINE CANCER

Gross Description

A. Received in formalin labeled "uterus, cervix, bilateral tubes and ovaries" is a hysterectomy specimen with attached bilateral adnexae, weighing a total of 80 grams. The uterus measures 6 cm from fundus to exocervix, 3 cm cornu to cornu and 4.5 cm anterior to posterior. The right fallopian tube measures 4 x 0.5 cm. The right ovary is yellow/tan and cystic in appearance and measures 2.5 x 2 x 1.5 cm. The left fallopian tube measures 4.5 x 0.5 cm. The left ovary is yellow/tan firm and measures 2 x 1.5 x 1 cm. The exocervix measures 1.5 x 1.2 x 1.1 cm. The uterus has been previously bivalved to show a gray-pink endocervical canal measuring 1.5 x 0.3 cm. The endometrial cavity has been previously sectioned and is remarkable for a gray/tan, friable papillary mass measuring 2.5 x 2 x 1.5 cm. The myometrium is 0.5 cm in thickness. Sectioning the anterior-posterior endomyometrium shows that the lesion involves >50% of the myometrium. The right fallopian tube is serially sectioned showing an unremarkable pinpoint

Prepared

[page 4 of 6]
lumen. The right ovary is serially sectioned to show a cyst with a clear fluid. No excrescence or papillation is grossly identified. The left fallopian tube is serially sectioned to show an unremarkable pinpoint lumen. The left ovary is serially sectioned to show a gray/tan atrophic parenchyma. The specimen is represented as follows: cervix is coned, radially sectioned and submitted as 12-3:00 in A1, 3-6:00 in A2-A3, 6-9:00 in A4, 9-12:00 in A5-A6; anterior lower uterine segment in A7; anterior endomyometrium and tumor at its deepest invasion in A8-A11; posterior lower uterine segment in A12; posterior endomyometrium and tumor at its deepest invasion in A13-A16; right fallopian tube, ovary and fimbria in A17; and left fallopian tube, ovary and fimbria in A18.

B. Received in formalin labeled with the patient's name and "vaginal cuff tissue" is a gray/tan tissue fragment measuring 1 x 0.5 cm. Wrapped and entirely submitted in B1.

C. Received in formalin labeled with the patient's name and "sigmoid surface tissue" is a gray/tan, fibrous tissue fragment measuring 3 x 2 cm. Entirely submitted in C1-C3.

D. Received in formalin labeled with the patient's name and "cul-de-sac" are gray/tan fibrous tissue fragments measuring 2 x 1.5 cm. Sectioned. Entirely submitted in D1-D2.

E. Received in formalin labeled with the patient's name and "left adnexal tissue" is a gray/tan, friable tissue fragment measuring 2 x 1.2 cm. Entirely submitted in E1.

F. Received in formalin labeled with the patient's name and "right side wall" is a gray/brown, fibrous and hemorrhagic tissue measuring 0.9 x 0.7 cm. Entirely submitted in F1.

G. Received in formalin labeled with the patient's name and "right pelvic lymph nodes" is a yellow/tan fibroadipose tissue measuring 0.7 x 0.5 cm consistent with lymphoid tissue. Bisected, wrapped and entirely submitted in G1.

H. Received in formalin labeled with the patient's name and "left pelvic lymph node" is a yellow/tan fibroadipose tissue measuring 1.5 x 0.7 cm consistent with lymph node. One lymph node is grossly identified measuring 0.7 x 0.4 cm. Bisected, wrapped and entirely submitted in H1.

I. Received in formalin labeled with the patient's name and "right side wall #2" is a yellow/tan, fibrous and hemorrhagic tissue fragment measuring 1.5 x 1 cm. Entirely submitted in I1.

J. Received in formalin labeled with the patient's name and "omentum" is a yellow/tan, firm and fibroadipose tissue measuring 20 x 4 x 2 cm. Sectioned to show three gray/tan nodules. The largest measures 3 x 2 cm; the smallest, 1.5 x 1 cm consistent with metastatic disease. Represented in J1-J2.

[page 5 of 6]
Procedure

A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
A. AA ROUTINE H&E X1 BLOCK.4
H&E X1
A. AA ROUTINE H&E X1 BLOCK.5
H&E X1
A. AA ROUTINE H&E X1 BLOCK.6
H&E X1
A. AA ROUTINE H&E X1 BLOCK.7
H&E X1
A. AA ROUTINE H&E X1 BLOCK.8
H&E X1
A. AA ROUTINE H&E X1 BLOCK.9
H&E X1
A. AA ROUTINE H&E X1 BLOCK.10
H&E X1
A. AA ROUTINE H&E X1 BLOCK.11
H&E X1
A. AA ROUTINE H&E X1 BLOCK.12
H&E X1
A. AA ROUTINE H&E X1 BLOCK.13
H&E X1
A. AA ROUTINE H&E X1 BLOCK.14
H&E X1
A. AA ROUTINE H&E X1 BLOCK.15
H&E X1
A. AA ROUTINE H&E X1 BLOCK.16
H&E X1
A. AA ROUTINE H&E X1 BLOCK.17
H&E X1
A. AA ROUTINE H&E X1 BLOCK.18
H&E X1
B. AA ROUTINE H&E X1 BLOCK
H&E X1 A RESULTS
C. AA ROUTINE H&E X1 BLOCK.1
H&E X1
C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
C. AA ROUTINE H&E X1 BLOCK.3
H&E X1

Prep:

[page 6 of 6]
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK
H&E X1
F. AA ROUTINE H&E X1 BLOCK
H&E X1
G. AA ROUTINE H&E X1 BLOCK
H&E X1
H. AA ROUTINE H&E X1 BLOCK
H&E X1 AE1/AE3
I. AA ROUTINE H&E X1 BLOCK
H&E X1
J. AA ROUTINE H&E X1 BLOCK.1
H&E X1
J. AA ROUTINE H&E X1 BLOCK.2
H&E X1

Prepared for

Source: NCI Genomic Data Commons file 95bc0118-b18c-43fb-84c7-486b22cdf462 (TCGA-K6-A3WQ.16F848AA-C14C-45F7-A756-414615853761.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).